CCDI case PBCNLV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9cef4e2b-de82-4e0e-a2ed-0a615bc06370

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (840 days).

Biospecimens (3 samples)
- Sample 0DW41O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW420: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW42H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
